Somatic mutation profile of tumor specimen C3L-02606-01 (aliquot CPT0124500006) from CPTAC case C3L-02606, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 68.9 years (25,148 days).
Specimen C3L-02606-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a65cd790-9483-45ed-ac6d-c45b8fb719b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02606-31 (Blood Derived Normal), aliquot CPT0124540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05dac171-912a-4c74-85f1-3877f4bf548c

The open-access MAF lists 62 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Intron 5, Nonsense Mutation 4, Splice Site 2, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 54/398 reads (14%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 41/374 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 70/365 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1022dup p.N342Efs*2 | Frame Shift Ins (INS) | VAF 28/167 reads (17%) | catalogued as rs746174250; called by mutect2, varscan2
- CCNA1 | c.719C>T p.T240M | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750419153, COSV55222625; called by muse, mutect2
- CDH24 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs764282796, COSV52974166; called by muse, mutect2, varscan2
- CHST1 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208095218, COSV57321999; called by muse, mutect2
- CYP11A1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as rs763099365, COSV51430559; called by muse, mutect2
- DOCK9 | c.3190A>T p.K1064* (on ENST00000376460 / NM_001366676.2; = p.K1065* on NM_015296.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 15/124 reads (12%) | catalogued as COSV59636152; called by muse, mutect2, varscan2
- EFNB1 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 57/408 reads (14%) | catalogued as CX084344; called by muse, mutect2, varscan2
- EIF4G2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 77/622 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.024); catalogued as COSV101150826; called by muse, mutect2, varscan2
- GGH | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.051); catalogued as rs554949020, COSV99479016; called by muse, mutect2, varscan2
- GIPR | c.385-1G>C p.X129_splice | Splice Site (SNP) | VAF 34/732 reads (5%) | catalogued as rs747744657; called by muse, mutect2
- GYS2 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 63/446 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs148461282; called by muse, mutect2, varscan2
- LRFN5 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV53242887; called by muse, mutect2
- LRRTM1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs1168813756, COSV99703402; called by muse, mutect2, varscan2
- PCDHA3 | c.103G>A p.V35I | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.123); catalogued as rs1554121379, COSV65366871; called by muse, mutect2, varscan2
- PCDHGA6 | c.1022A>G p.N341S | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as rs371346343, COSV54018804; called by muse, mutect2, varscan2
- POTEJ | c.2092G>A p.V698M | Missense Mutation (SNP) | VAF 123/759 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs761434672; called by muse, mutect2, varscan2
- RNF103 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1262913118, COSV52896064; called by muse, mutect2, varscan2
- SETBP1 | c.3961C>T p.R1321C | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767301100; ClinVar: likely benign; called by muse, mutect2
- SPTA1 | c.3743G>A p.R1248Q | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs568044940, COSV63753987; called by muse, mutect2, varscan2
- TFR2 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.862); catalogued as rs920217192; called by muse, mutect2, varscan2
- TTN | c.59080G>A p.E19694K (on ENST00000591111; = p.E12270K on NM_003319.4) | Missense Mutation (SNP) | VAF 94/534 reads (18%) | PolyPhen probably damaging (0.994); catalogued as rs773791222, COSV60221006; called by muse, mutect2, varscan2
- UNC5C | c.1022C>T p.T341M | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.594); catalogued as rs775796452, COSV71661666; called by muse, mutect2
- VLDLR | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 57/463 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs769791140; called by muse, mutect2, varscan2
- ZNF433 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1204422588, COSV61398493; called by muse, mutect2, varscan2
- ACE | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CSRNP2 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 25/348 reads (7%) | called by muse, mutect2
- DYNC2H1 | c.11058G>T p.L3686F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- EFCAB3 | c.835T>C p.Y279H | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ETV4 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARS2 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FOXI1 | c.220C>G p.P74A | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.033); called by muse, mutect2
- OR5AP2 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCDHA5 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); called by muse, mutect2
- PCF11 | c.119T>A p.L40Q | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PREX2 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 18/470 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2
- RNF19A | c.1683G>A p.R561= | Splice Region (SNP) | VAF 30/276 reads (11%) | called by muse, varscan2
- TEDC2 | c.197-2A>G p.X66_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- TRIM56 | c.1129_1131del p.K377del | In Frame Del (DEL) | VAF 16/131 reads (12%) | called by mutect2, pindel, varscan2
- TRIM71 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- UMODL1 | c.3547del p.T1183Hfs*5 (on ENST00000408910 / NM_001004416.2; = p.T1311Hfs*5 on NM_173568.3) | Frame Shift Del (DEL) | VAF 30/228 reads (13%) | called by mutect2, pindel, varscan2
- BRWD3 | c.1023G>C p.V341= | Silent (SNP) | VAF 15/198 reads (8%) | called by muse, mutect2
- CACNA1I | c.5649C>T p.G1883= | Silent (SNP) | VAF 16/143 reads (11%) | called by muse, mutect2, varscan2
- CDH7 | c.531G>A p.A177= | Silent (SNP) | VAF 34/377 reads (9%) | catalogued as rs567500655, COSV59881966; called by muse, mutect2
- COL6A5 | c.1665C>T p.S555= | Silent (SNP) | VAF 32/412 reads (8%) | catalogued as COSV55196411; called by muse, mutect2
- ERFE | c.207C>T p.T69= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs970950289, COSV60137478; called by muse, mutect2, varscan2
- GRIP2 | c.1392C>T p.P464= (on ENST00000619221; = p.P367= on NM_001080423.4) | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as rs892714157; called by muse, mutect2, varscan2
- ITPKC | c.399G>C p.T133= | Silent (SNP) | VAF 24/792 reads (3%) | called by muse, mutect2
- KSR2 | c.1584G>A p.T528= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs753143776, COSV56676969; called by muse, mutect2
- LMX1A | c.174G>A p.Q58= | Silent (SNP) | VAF 19/404 reads (5%) | called by muse, mutect2
- PCDH8 | c.489C>T p.D163= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV58810931; called by muse, mutect2, varscan2
- TMC3 | c.141G>A p.P47= | Silent (SNP) | VAF 18/296 reads (6%) | catalogued as rs375088581; called by muse, mutect2
- ZNF148 | c.2043T>C p.G681= | Silent (SNP) | VAF 25/313 reads (8%) | called by muse, mutect2
- ATPSCKMT | chr5:10249897 del TA | 5'Flank (DEL) | VAF 27/91 reads (30%) | catalogued as rs1561039450; called by mutect2, varscan2*
- EYS | c.1767-6583G>A | Intron (SNP) | VAF 50/450 reads (11%) | catalogued as rs767825310; called by muse, mutect2, varscan2
- FLNB | c.542-237A>G | Intron (SNP) | VAF 40/217 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10594C>T | Intron (SNP) | VAF 19/257 reads (7%) | catalogued as rs1261477358, COSV57130946; called by muse, mutect2
- NAB2 | c.-33G>A | 5'UTR (SNP) | VAF 24/330 reads (7%) | catalogued as rs1351301604; called by muse, mutect2
- TTYH1 | c.126+1193C>G | Intron (SNP) | VAF 79/289 reads (27%) | called by muse, mutect2, varscan2
- UBE2D3 | c.25-1883C>G | Intron (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
